Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5SF, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5SF-01A (Primary Tumor).

ICD-O-3
Melanoma, Nodular 8721/3
Site Skin of Extremity C44.9
QW 2/18/13

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Skin, extremity

Tumor size: 2 x 1.1 x 1.1 cm

Tumor features: Ulcerated, Raised, Pigmented

Satellite nodules: Not specified

Histologic type: Nodular melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: 5th level of invasion by Clarc. 11 mm deep

Comments: None

Case is a duplicate		/

Source: NCI Genomic Data Commons file 5bc0ea46-4706-48c6-a575-abad34250eee (TCGA-EB-A5SF.B846EC32-BF45-498A-B136-324AE678F890.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).